Somatic mutation profile of tumor specimen TCGA-20-1686-01A (aliquot TCGA-20-1686-01A-01W-0633-09) from TCGA case TCGA-20-1686, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 75.5 years (27,588 days).
Specimen TCGA-20-1686-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba454378-50aa-4a12-b76a-0f23b7a79ced.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-20-1686-10A (Blood Derived Normal), aliquot TCGA-20-1686-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05129459-a31a-4d01-bcea-5ff828f150a4

The open-access MAF lists 98 somatic variants for this specimen: 78 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 19, Nonsense Mutation 6, Splice Site 2, Frame Shift Del 2, In Frame Del 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PYGM | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377225525, CM076447; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 31/42 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSL4 | c.1253C>T p.P418L (on ENST00000340800 / NM_022977.2; = p.P377L on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61613351; called by muse, mutect2, varscan2
- ALDOA | c.1184G>A p.G395E (on ENST00000642816 / NM_001243177.4; = p.G341E on NM_184041.5) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV57632029; called by muse, mutect2, varscan2
- ANXA5 | c.913T>A p.S305T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV56638289; called by muse, mutect2, varscan2
- ARHGAP31 | c.3223G>A p.V1075M | Missense Mutation (SNP) | VAF 98/640 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs777789268, COSV51789384; called by muse, mutect2, varscan2
- ASPM | c.5156C>T p.A1719V | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.05); catalogued as rs1557947620, COSV54125004, COSV54136604; called by muse, mutect2, varscan2
- ASPN | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 39/105 reads (37%) | catalogued as rs148382623, COSV65016788; called by muse, mutect2, varscan2
- BRINP1 | c.1714T>G p.S572A | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV56292579, COSV99776241; called by muse, mutect2, varscan2
- C1orf87 | c.1193-1G>C p.X398_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as rs764456068, COSV64596129; called by muse, mutect2, varscan2
- CACNA2D1 | c.3125A>G p.N1042S (on ENST00000356253 / NM_001366867.1; = p.N1030S on NM_000722.4) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV62373234; called by muse, mutect2, varscan2
- CBFA2T2 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.204); catalogued as rs57375754, COSV60800443; called by muse, mutect2, varscan2
- CCR4 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100447291; called by muse, mutect2
- CD200 | c.472G>T p.G158* (on ENST00000473539 / NM_001004196.3; = p.G133* on NM_005944.7 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/322 reads (3%) | catalogued as COSV100238172; called by muse, mutect2
- CNGA2 | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.009); catalogued as COSV61703341; called by muse, mutect2, varscan2
- COL19A1 | c.735A>G p.I245M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV59565847; called by muse, mutect2, varscan2
- COL4A4 | c.3074C>G p.P1025R | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.694); catalogued as COSV61629737; called by muse, mutect2, varscan2
- CRB1 | c.3856C>G p.R1286G | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV66328778; called by muse, mutect2, varscan2
- CRMP1 | c.73A>G p.I25V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61478371; called by muse, mutect2, varscan2
- CSMD3 | c.6878C>A p.T2293N (on ENST00000297405 / NM_001363185.1; = p.T2189N on NM_052900.3) | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52107746; called by muse, mutect2, varscan2
- DAP3 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV58019268; called by muse, mutect2, varscan2
- DHPS | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 54/767 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV99269527; called by muse, mutect2
- DNAH2 | c.2606T>A p.L869* | Nonsense Mutation (SNP) | VAF 16/176 reads (9%) | catalogued as COSV101209055; called by muse, mutect2
- DPP3 | c.1145C>A p.A382D | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV64756064, COSV64757168; called by muse, mutect2, varscan2
- DST | c.15011T>C p.M5004T (on ENST00000361203 / NM_001374722.1; = p.M2592T on NM_015548.5) | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV54998970; called by muse, mutect2, varscan2
- DST | c.6822A>T p.K2274N | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV99751996; called by muse, mutect2
- EBAG9 | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV61752703; called by muse, mutect2, varscan2
- FAM135B | c.2711C>A p.P904Q | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.467); catalogued as COSV99420005; called by muse, mutect2
- FICD | c.786C>G p.N262K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99933897; called by muse, varscan2
- FRAS1 | c.7171G>A p.G2391S | Missense Mutation (SNP) | VAF 67/523 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as rs990501513, COSV53604893; called by muse, mutect2, varscan2
- FRMPD2 | c.3520C>A p.L1174M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs2258914, COSV59719348; called by muse, mutect2
- FRMPD2 | c.2532G>C p.R844S | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV59715340; called by muse, mutect2, varscan2
- G6PD | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.197); catalogued as CM950513, COSV63702336; called by muse, mutect2, varscan2
- GABRB3 | c.1385T>G p.L462R | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100158508; called by muse, mutect2
- GAPVD1 | c.2120T>A p.I707K | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52924333, COSV99782731; called by muse, mutect2
- GPR139 | c.197T>G p.L66R | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429666; called by muse, mutect2
- GYG1 | c.837C>A p.D279E | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV56048749; called by muse, mutect2, varscan2
- HMMR | c.1336G>C p.D446H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100700971; called by muse, mutect2
- IGF2BP1 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51729304; called by muse, mutect2, varscan2
- KIAA0100 | c.2263G>C p.E755Q | Missense Mutation (SNP) | VAF 20/377 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV101197227; called by muse, mutect2
- KIAA2013 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as rs765034916, COSV64860291; called by muse, mutect2, varscan2
- MAGED2 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 87/144 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV54496979; called by muse, mutect2, varscan2
- MAP3K12 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.277); catalogued as COSV57231325; called by muse, mutect2, varscan2
- MUC17 | c.6353A>G p.E2118G | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV60280759, COSV60294837; called by muse, mutect2, varscan2
- MYO1B | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 6/180 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100268742; called by muse, mutect2
- N6AMT1 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV58133716; called by muse, mutect2, varscan2
- NAALADL2 | c.742A>C p.S248R | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV101458166; called by muse, mutect2
- NDUFAF1 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs751866388, COSV52974755; called by muse, mutect2, varscan2
- NOTCH3 | c.5404dup p.A1802Gfs*8 | Frame Shift Ins (INS) | VAF 10/72 reads (14%) | catalogued as rs753725730; called by mutect2, varscan2
- PADI1 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 34/122 reads (28%) | catalogued as COSV64937799; called by muse, mutect2, varscan2
- PDP1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99891997; called by muse, mutect2
- PKD2L1 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV58394654; called by muse, mutect2
- PREX1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs375685234; called by muse, mutect2, varscan2
- PRG2 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 87/299 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs750810108, COSV61293071; called by muse, mutect2, varscan2
- PRPF8 | c.4120C>T p.P1374S | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.057); catalogued as COSV100517202; called by muse, mutect2
- RIT2 | c.233A>C p.Q78P | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99949738; called by muse, mutect2
- SEMA5A | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs774783706, COSV66785181; called by muse, mutect2, varscan2
- SGO2 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 81/318 reads (25%) | catalogued as COSV63413981; called by muse, mutect2, varscan2
- SIPA1L2 | c.1880A>G p.N627S | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV53383962, COSV53401947; called by muse, mutect2, varscan2
- SLCO3A1 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.349); catalogued as COSV59225286; called by muse, mutect2, varscan2
- SLIT2 | c.2494C>G p.L832V | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs777317760, COSV56561075; called by muse, mutect2, varscan2
- SPATA31E1 | c.1991C>G p.P664R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.607); catalogued as COSV57789578; called by muse, mutect2, varscan2
- STRIP2 | c.931G>C p.V311L | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.26); catalogued as COSV50803322; called by muse, mutect2, varscan2
- TRIM5 | c.514-1G>A p.X172_splice | Splice Site (SNP) | VAF 26/53 reads (49%) | catalogued as COSV59898715; called by muse, mutect2, varscan2
- TTF2 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 14/134 reads (10%) | catalogued as COSV101037303; called by muse, mutect2
- UBE2Q1 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52723953; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3365C>T p.S1122L | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99511538; called by muse, mutect2
- USP15 | c.781T>C p.S261P (on ENST00000280377 / NM_001351159.2; = p.S232P on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as COSV54788096; called by muse, mutect2, varscan2
- WASHC2C | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 62/554 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV60490185; called by muse, varscan2
- ZNF266 | c.1261T>A p.S421T | Missense Mutation (SNP) | VAF 20/461 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.914); catalogued as COSV100749348; called by muse, mutect2
- ZNF324B | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60740610; called by muse, mutect2, varscan2
- ZNF440 | c.1276T>C p.C426R | Missense Mutation (SNP) | VAF 28/480 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100407408; called by muse, mutect2
- ZNF638 | c.4615G>C p.D1539H | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52482258; called by muse, mutect2, varscan2
- ZNF675 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV100704937; called by muse, mutect2
- DHX30 | c.2493+1del | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- GUF1 | c.375_385del p.F126* | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, varscan2
- RLN3 | c.403_426del p.K135_C142del | In Frame Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- TRMT2B | c.775_777del p.K259del | In Frame Del (DEL) | VAF 25/101 reads (25%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.885G>A p.V295= | Silent (SNP) | VAF 51/134 reads (38%) | catalogued as COSV61256087; called by muse, mutect2, varscan2
- C7orf31 | c.1170T>C p.H390= | Silent (SNP) | VAF 52/305 reads (17%) | catalogued as COSV52216099; called by muse, mutect2, varscan2
- CD200 | c.471A>C p.S157= (on ENST00000473539 / NM_001004196.3; = p.S132= on NM_005944.7 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 9/326 reads (3%) | catalogued as COSV100238170; called by muse, mutect2
- CHD7 | c.7761A>G p.K2587= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as COSV71107338; called by mutect2, varscan2
- CIT | c.6G>A p.L2= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV55860669; called by muse, mutect2, varscan2
- CYLC1 | c.285G>A p.R95= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as COSV61410034; called by muse, mutect2, varscan2
- DCC | c.2436C>T p.A812= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs761106983, COSV59085806; called by muse, mutect2, varscan2
- DLGAP1 | c.648C>T p.H216= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV59785491; called by muse, mutect2, varscan2
- FNDC1 | c.594C>T p.Y198= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs531853879, COSV51931287; called by mutect2, varscan2
- KDM4C | c.2034G>A p.S678= | Silent (SNP) | VAF 70/311 reads (23%) | catalogued as rs766460763, COSV101184977, COSV67183810; called by muse, mutect2, varscan2
- KIAA1549L | c.5121T>C p.N1707= (on ENST00000321505; = p.N2004= on NM_012194.3) | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100380983; called by muse, mutect2
- LRP1B | c.7587C>A p.T2529= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV67188606; called by muse, mutect2, varscan2
- LTN1 | c.4956G>A p.L1652= | Silent (SNP) | VAF 92/351 reads (26%) | catalogued as COSV63733027; called by muse, mutect2, varscan2
- NLRP14 | c.2568T>A p.G856= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV55064297; called by muse, mutect2, varscan2
- NQO2 | c.369G>A p.Q123= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs771845813, COSV57642363; called by muse, mutect2, varscan2
- PHF3 | c.3930T>C p.D1310= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- POTED | c.513G>A p.K171= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV55046776; called by muse, mutect2, varscan2
- SEC23B | c.1548A>G p.E516= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV99357466; called by muse, mutect2
- SEMG1 | c.849A>T p.A283= | Silent (SNP) | VAF 14/286 reads (5%) | catalogued as COSV99725092; called by muse, mutect2
- AC244258.1 | n.526T>A | RNA (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
